Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2GD, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2GD-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex:

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Known metastatic melanoma (R) leg and thigh. Excision of multiple tumours (R) leg + thigh as labelled.

MACROSCOPIC DESCRIPTION

(Dr

ICD - 0 - 3
Melanoma, NOS 8720/3
Site: Subcutaneous tissue, leg C49.2
4/10/11 for

Seven specimens were received.

1. "TUMOUR RIGHT LEG POSTERIOR". An oval shaped skin excision, measuring 48 x 43 x 23mm, with an ulcerated nodule, 22 x 20mm towards one edge. Underlying this, a pale lobulated tumour is identified abutting on the deep and transverse margins along the entire specimen length within the subcutaneous tissues.

One representative section submitted in block A. Section through nodule taken for Tumour Bank.

2. "TUMOUR RIGHT ANTERIOR LEG LOWER". An nodular polypoid mass with a flat base measuring 55 x 53 x 28mm (base 28 x 22mm). The entire surface of the nodule appears tumorous. (The base is inked black). The tumour is white and lobulated and appears to abut on the resection margin at the base. One representative section bisected and submitted in blocks A and B.

3. "TUMOUR RIGHT ANTERIOR LEG MID". An oval excision of skin 20 x 14mm with a skin thickness of 2mm and a centrally located, white nodule 15 x 12mm that appears to be on the skin surface, raised 2mm above the surface. The resection margin appears involved laterally. Three representative sections submitted in block A.

4. "TUMOUR LATERAL RIGHT LOWER LEG". An oval shaped excision of skin, 15 x 12mm to a total thickness of 3mm including the lesion. There is a white nodule, 11 x 13mm, that appears to be on the skin surface and raised 4mm above the surface. It appears to abut on the transverse margins in multiple regions. Specimen divided into four transverse sections and submitted in block A. All embedded.

5. "TUMOUR RIGHT ANKLE". An irregularly shaped excision of skin, 40 x 27 x 12mm, with two surface nodular protrusions one at each pole. One nodule is ulcerated on the surface, measuring 22 x 15mm, and the other nodule is non-ulcerated, 16 x 17mm. Between these nodules there is a pale, lobulated tumour within the subcutaneous tissues which abuts on the deep and transverse subcutaneous surgical resection margins. Two sections through the ulcerated nodule in blocks A. Two sections through the non-ulcerated nodule in block B.

6. "TUMOUR RIGHT THIGH POSTERIOR". An oval excision of skin 26 x 25mm to a thickness of 22mm with an underlying subcutaneous pale lobulated nodule that abuts all transverse margins and the deep margin. One representative section submitted in block A.

7. "DEEPER TUMOUR RIGHT POSTERIOR THIGH". Five irregularly shaped fragments of firm pale tissue, 40 x 40 x 15mm in aggregate. One section through each piece submitted.

A. Two sections.

[page 2 of 2]
Requested by: -

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

B. Three sections. All tissue appears lesional

MICROSCOPIC REPORT

1. Sections show a deposit of tumour consistent with malignant melanoma within the dermis and subcutaneous tissue. Immunostaining for S100 is positive in tumour cells while keratin AE1/AE3 and Cam 5.2 are negative. No epidermal involvement is present. The tumour extends to the deep and to both lateral/transverse resection margins on a broad front.

2. Sections show a deposit of moderately differentiated keratinising squamous cell carcinoma within dermis and subcutis. Immunostaining for keratin AE1/AE3 and Cam 5.2 is positive in the tumour cells while staining for S100, HMB45, Melan A and tyrosinase is negative. No epidermal involvement is identified. The tumour extends to the deep resection margin.

3. Sections show a deposit of tumour consistent with malignant melanoma within the dermis. Immunostaining for S100 is positive in tumour cells while keratin AE1/AE3 and Cam 5.2 are negative. No epidermal involvement is identified. The tumour extends to the deep resection margin over a broad front.

4. Sections show a deposit of tumour consistent with malignant melanoma within the dermis. Immunostaining for S100 is positive in tumour cells while keratin AE1/AE3 and Cam 5.2 are negative. No epidermal involvement is identified. The tumour extends to the deep resection margin over a broad front.

5. Sections show deposits of tumour consistent with malignant melanoma involving the dermis and subcutis. Immunostaining for keratin AE1/AE3 and Cam 5.2 are negative. No epidermal involvement is identified. The tumours extend to the deep and transverse/lateral resection margins over a broad front.

6. Sections show a deposit of tumour consistent with malignant melanoma within dermis and subcutis. No epidermal involvement is identified. The tumour extends to the deep and transverse resection margins over a broad front.

7. Sections show a deposit of tumour consistent with malignant melanoma.

SUMMARY

1. Right leg posterior: **Malignant melanoma.**

/

2. Right anterior leg lower: **Squamous cell carcinoma**

Squamous cell carcinoma

/

3. Right anterior leg mid: **Malignant melanoma.**

/

4. Lateral right lower leg: **Malignant melanoma.**

/

5. Right ankle: **Malignant melanoma.**

/

6. Right thigh posterior: **Consistent with malignant melanoma.**

/

7. Deeper tumour right posterior thigh: **Consistent with malignant melanoma.**

REPORTED BY

Source: NCI Genomic Data Commons file 06f5da13-15e2-4029-9c23-fbd20fb81eff (TCGA-EE-A2GD.E7219620-4E00-4484-BBF1-3311C52321F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).